Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACR2, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACR2-TTP1-A (Primary Tumor).

Material to be examined and removal site:

1. Left lung
2. Lymph nodes

CDDP-YP-ACR2-01-PR

**Macroscopic report:**

1. Lung of cm 21x12x6, in the upper lobe sub pleurally, It presents a neoplasm distant cm 5 from the bronchial margin. In the peribronchial lymph node is replaced of cm 2 of diameter.
2. One lymph node

Histopathological diagnosis

1. Poorly differentiated adenocarcinoma with areas of necrosis and surrounding sub-acute inflammatory reaction with massive obliteration of alveolar. It is visceral pleural involvement.
The bronchial margin is harmless but one peribronchial lymph node is site of massive metastases, while others five are free.
2. Reactive lymph node

Codes SNOMED

T-28000 M-81403

ICD-0-3

Adenocarcinoma, NOS 8140/3

Site: (L) lung, upper lobe c34.1

ICD-10

C34.12

Source: NCI Genomic Data Commons file 88864abc-e7d1-4c57-a64b-2001dc910f8c (CDDP-ACR2-TTP1.AD37D158-B2BD-4C90-BFB7-42F3CF339250.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).